CPTAC case C3L-05299 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c8c3197d-93e8-4933-9c67-ae488e220d72

Demographics
Sex at birth: male; Race: white; Year of birth: 1946; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 72.3 years (26,405 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,749 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,749 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 6; Margin status: Indeterminate.

Follow-up (5 entries)
- Days to follow up: 470 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 639 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 1,014 days (2.8 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,463 days (4.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,749 days (4.8 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-05299-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 243 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05299-24: Section location: Lymph node; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3L-05299-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 169 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-05299-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
